Somatic mutation profile of tumor specimen ALCH-ADPQ-TTP1-A (aliquot ALCH-ADPQ-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADPQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.8 years (29,500 days).
Specimen ALCH-ADPQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5960f35d-2d40-45fc-aeb8-4d4db649f29c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADPQ-NB1-A (Blood Derived Normal), aliquot ALCH-ADPQ-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5c3afef-8fda-4095-955b-42b521a36cc9

The open-access MAF lists 484 somatic variants for this specimen: 319 protein-altering or splice-affecting, 98 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 264, Silent 98, Intron 27, Nonsense Mutation 23, 5'UTR 14, Splice Site 12, 3'UTR 10, RNA 8, Frame Shift Del 8, Splice Region 6, Frame Shift Ins 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.8329C>T p.R2777* | Nonsense Mutation (SNP) | VAF 154/845 reads (18%) | catalogued as rs886039330, CM096540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 78/606 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 125/977 reads (13%) | catalogued as rs387906683, CM044709; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 226/1345 reads (17%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 242/766 reads (32%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 148/1366 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs200288646, COSV53966033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.4655G>T p.G1552V | Missense Mutation (SNP) | VAF 302/1029 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.219); catalogued as COSV61369171; called by muse, mutect2, varscan2
- ACSM5 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 68/387 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV59375716; called by muse, mutect2, varscan2
- ADCY9 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs144319192; called by muse, varscan2
- ANKFN1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 250/737 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV59439805, COSV59447659; called by muse, mutect2, varscan2
- ANKRD13B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs1555581491; called by muse, mutect2, varscan2
- ANKS3 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 155/414 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.313); catalogued as COSV100423372; called by muse, mutect2, varscan2
- AP2A2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 94/467 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59962495; called by muse, mutect2, varscan2
- APLF | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 239/944 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV58144074; called by muse, mutect2, varscan2
- ARFGEF3 | c.4190G>T p.R1397L | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV52449312, COSV52470397; called by muse, mutect2, varscan2
- BCKDHB | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 340/1248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM014511, CM124309, COSV57509117; called by muse, mutect2, varscan2
- BPIFB2 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 151/571 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV50063711; called by muse, mutect2, varscan2
- BRCA1 | c.5087T>A p.V1696E | Missense Mutation (SNP) | VAF 311/975 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs397509226, CM087391; ClinVar: not provided; called by muse, mutect2, varscan2
- BTBD11 | c.2308G>A p.E770K (on ENST00000280758 / NM_001018072.2; = p.E307K on NM_001017523.2) | Missense Mutation (SNP) | VAF 60/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1415961019, COSV55022441, COSV55024035; called by muse, mutect2, varscan2
- C12orf57 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.993); catalogued as rs146701570; called by muse, mutect2, varscan2
- CADM2 | c.1108A>T p.I370L (on ENST00000407528 / NM_001167674.2; = p.I372L on NM_153184.4) | Missense Mutation (SNP) | VAF 33/461 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV67360866; called by muse, mutect2
- CD163L1 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 467/1739 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs774381093, COSV58011002; called by muse, mutect2, varscan2
- CELSR1 | c.3830C>T p.S1277L | Missense Mutation (SNP) | VAF 147/424 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs199750230, COSV53085833; called by muse, mutect2, varscan2
- CEP41 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 169/902 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781878740; called by muse, mutect2, varscan2
- COL5A1 | c.3436G>T p.A1146S | Missense Mutation (SNP) | VAF 153/698 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV65665969; called by muse, mutect2, varscan2
- CPLX4 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 80/638 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.694); catalogued as COSV55314819; called by muse, varscan2
- CUL9 | c.6499G>A p.D2167N | Missense Mutation (SNP) | VAF 71/509 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs756946015, COSV99335443; called by muse, mutect2, varscan2
- CXCL1 | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 93/488 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs760965523; called by muse, mutect2, varscan2
- CXorf21 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 67/492 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV66762472, COSV66763043; called by muse, mutect2, varscan2
- DEPDC1B | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 104/547 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs778143900; called by muse, mutect2, varscan2
- DMD | c.7468G>C p.D2490H | Missense Mutation (SNP) | VAF 188/1592 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as COSV58952570, COSV58962135; called by muse, mutect2, varscan2
- DMD | c.6823G>T p.G2275* | Nonsense Mutation (SNP) | VAF 600/1798 reads (33%) | catalogued as COSV58953849; called by muse, mutect2, varscan2
- EPN3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as rs374859710; called by muse, mutect2, varscan2
- EPPK1 | c.4369G>T p.V1457F | Missense Mutation (SNP) | VAF 196/440 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs781922344; called by muse, mutect2, varscan2
- ERICH5 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 112/750 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.177); catalogued as COSV100582708; called by muse, mutect2, varscan2
- EZHIP | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 69/432 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV100539658, COSV100539891; called by muse, mutect2, varscan2
- F13B | c.1805A>G p.N602S | Missense Mutation (SNP) | VAF 100/890 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs763591423; called by muse, mutect2, varscan2
- FAM166C | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 140/819 reads (17%) | catalogued as COSV56604062; called by muse, mutect2, varscan2
- FAM47B | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 231/751 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61452280; called by muse, mutect2, varscan2
- FAU | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 54/742 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1464728387, COSV54195478; called by muse, mutect2
- GIN1 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV101204421; called by muse, mutect2, varscan2
- GLYAT | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 140/546 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV53540831; called by muse, mutect2, varscan2
- GOLGA8J | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 139/1246 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191597402; called by muse, mutect2, varscan2
- GPLD1 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 123/360 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs142854013; called by muse, mutect2, varscan2
- GPR45 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 222/1018 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200554082; called by muse, mutect2, varscan2
- IL20RB | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 77/834 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV59047630; called by muse, mutect2
- ITPR3 | c.4999C>T p.R1667W | Missense Mutation (SNP) | VAF 79/724 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs888688235; called by muse, mutect2, varscan2
- KATNIP | c.4450-1G>A p.X1484_splice | Splice Site (SNP) | VAF 220/604 reads (36%) | catalogued as COSV55193508; called by muse, mutect2, varscan2
- KCND1 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 221/723 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs1282997974, COSV54412783; called by muse, mutect2, varscan2
- KIAA0319 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 82/521 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs781339357; called by muse, mutect2, varscan2
- KIF6 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 82/579 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs755557178, COSV99756507; called by muse, mutect2, varscan2
- KLHL34 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs749821216; called by muse, mutect2, varscan2
- LRIT1 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100928025; called by muse, mutect2, varscan2
- MAGEB2 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 236/944 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100975607; called by muse, mutect2, varscan2
- METTL18 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 117/897 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs368584829; called by muse, mutect2, varscan2
- MYOCD | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 165/477 reads (35%) | catalogued as COSV58506546; called by muse, mutect2, varscan2
- N4BP2L1 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV58413000; called by muse, mutect2, varscan2
- NAV3 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 249/531 reads (47%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99891495; called by muse, mutect2, varscan2
- NFASC | c.1431C>G p.N477K (on ENST00000339876 / NM_001378329.1; = p.N488K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/2088 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV58366544; called by muse, mutect2, varscan2
- NLGN4X | c.1382C>A p.A461E | Missense Mutation (SNP) | VAF 311/1234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52003690; called by muse, mutect2, varscan2
- NLRP12 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 542/2254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1006682366, COSV100145563, COSV60743086; called by muse, mutect2, varscan2
- NOD1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs775775470; called by muse, mutect2, varscan2
- OR10G8 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 107/553 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV70909015; called by muse, mutect2, varscan2
- OR2AG1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745849873, COSV56626367, COSV56626473; called by muse, mutect2, varscan2
- OR2F1 | c.719C>G p.T240R | Missense Mutation (SNP) | VAF 302/574 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67332095; called by muse, mutect2, varscan2
- OR5D16 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs746124717, COSV65722161; called by muse, mutect2, varscan2
- OR5M3 | c.706T>A p.F236I | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV56567784; called by muse, mutect2, varscan2
- OR6M1 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100484116; called by muse, mutect2, varscan2
- OR8K5 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57890666; called by muse, mutect2, varscan2
- OR9G4 | c.206del p.L69Wfs*39 | Frame Shift Del (DEL) | VAF 121/545 reads (22%) | catalogued as rs781668122; called by mutect2, pindel, varscan2
- OSTN | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 116/1838 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV59139348; called by muse, mutect2
- OTC | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 60/1268 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV50002988; called by muse, mutect2
- PABPC5 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 112/1384 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57039791; called by muse, mutect2
- PASD1 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 73/619 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100949446, COSV64856045; called by muse, mutect2, varscan2
- PCDH15 | c.4262C>A p.A1421E | Missense Mutation (SNP) | VAF 172/841 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV57262088; called by muse, mutect2, varscan2
- PCDHGB5 | c.2135G>T p.R712L | Missense Mutation (SNP) | VAF 131/618 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs1485452553, COSV53998393; called by muse, mutect2, varscan2
- PDCD1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 170/996 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs568397742; called by muse, mutect2, varscan2
- PODN | c.1113C>A p.S371R (on ENST00000395871; = p.S323R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/468 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs183323876, COSV57018082; called by muse, mutect2, varscan2
- POM121L2 | c.600G>C p.M200I | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66277317; called by muse, mutect2, varscan2
- PRDX4 | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101028562; called by muse, mutect2, varscan2
- RASSF3 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 260/480 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51686992; called by muse, mutect2, varscan2
- RBFOX1 | c.445G>T p.E149* (on ENST00000641259; = p.E33* on NM_001308117.1) | Nonsense Mutation (SNP) | VAF 49/280 reads (18%) | catalogued as COSV104436932; called by muse, mutect2, varscan2
- RELN | c.4160G>C p.R1387P | Missense Mutation (SNP) | VAF 241/1312 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634332, COSV59020316; called by muse, mutect2, varscan2
- SIGLEC11 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs1158145101; called by muse, mutect2, varscan2
- SLC39A6 | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 39/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368642; called by muse, mutect2
- SLC45A2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 145/848 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs888610793, COSV99673039; called by muse, mutect2, varscan2
- SLC5A10 | c.1054G>A p.A352T (on ENST00000395645 / NM_001042450.4; = p.A368T on NM_152351.5) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs370149434; called by muse, mutect2, varscan2
- SNCAIP | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 209/919 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs763376254, COSV54422215; called by muse, mutect2, varscan2
- SNRNP70 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV55506292; called by mutect2, varscan2
- SNX12 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52145969; called by muse, varscan2
- SORCS2 | c.1452C>A p.S484R | Missense Mutation (SNP) | VAF 110/547 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV100213309; called by muse, mutect2, varscan2
- ST18 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 80/676 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV52491659; called by muse, mutect2, varscan2
- ST6GAL1 | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 61/918 reads (7%) | PolyPhen benign (0.334); catalogued as rs188879099; called by muse, mutect2
- SUPT3H | c.505G>A p.E169K (on ENST00000371460 / NM_181356.3; = p.E158K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/682 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.851); catalogued as rs1232194875; called by muse, mutect2, varscan2
- SYCE1 | c.595+3G>A | Splice Region (SNP) | VAF 54/256 reads (21%) | catalogued as rs759424252, COSV100385735, COSV58218403; called by muse, varscan2
- TBC1D8B | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 44/1281 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1187553121; called by muse, mutect2
- TLE6 | c.564G>T p.Q188H (on ENST00000246112 / NM_001143986.2; = p.Q65H on NM_024760.3) | Missense Mutation (SNP) | VAF 95/487 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.693); catalogued as COSV55737890; called by muse, mutect2, varscan2
- TLE6 | c.565G>A p.E189K (on ENST00000246112 / NM_001143986.2; = p.E66K on NM_024760.3) | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as COSV55736433, COSV55737189; called by muse, mutect2, varscan2
- TLR5 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs775858795; called by muse, mutect2
- TMC8 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs1035555956; called by muse, mutect2, varscan2
- TMEM163 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 79/791 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56112781; called by muse, mutect2, varscan2
- TMEM41B | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs760231133; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 103/960 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139813482; called by muse, mutect2, varscan2
- TRAV8-2 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 203/1010 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs751243668; called by muse, mutect2, varscan2
- TTN | c.23362C>A p.P7788T (on ENST00000591111; = p.P6861T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/463 reads (14%) | PolyPhen benign (0.037); catalogued as COSV59901358; called by muse, mutect2, varscan2
- TTN | c.19940C>G p.T6647R (on ENST00000591111; = p.T5720R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/260 reads (11%) | PolyPhen benign (0.438); catalogued as COSV60026146; called by muse, mutect2, varscan2
- UBAP2 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 138/737 reads (19%) | catalogued as rs757022773, COSV100670767, COSV62545130; called by muse, mutect2, varscan2
- VSIG4 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 156/520 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101038097; called by muse, mutect2, varscan2
- ZFHX4 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 256/701 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV51450351; called by muse, mutect2, varscan2
- ZNF345 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 111/816 reads (14%) | catalogued as COSV59323502; called by muse, mutect2, varscan2
- ZNF407 | c.2399A>G p.H800R | Missense Mutation (SNP) | VAF 317/604 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as rs759325536, COSV55267902; called by muse, mutect2, varscan2
- ZNF526 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 248/924 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs1032908026; called by muse, mutect2, varscan2
- ZNF676 | c.310G>C p.D104H (on ENST00000650058; = p.D72H on NM_001001411.3) | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV68092156; called by muse, mutect2, varscan2
- ZNF98 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63336914; called by mutect2, varscan2
- ABCA13 | c.4205A>G p.N1402S | Missense Mutation (SNP) | VAF 104/762 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ABCC9 | c.4378G>A p.A1460T | Missense Mutation (SNP) | VAF 221/1946 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACSM5 | c.1537-1G>T p.X513_splice | Splice Site (SNP) | VAF 68/380 reads (18%) | called by muse, mutect2, varscan2
- ACVR2A | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 131/542 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS18 | c.3156C>A p.S1052R | Missense Mutation (SNP) | VAF 186/487 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK1 | c.1334dup p.T447Hfs*21 | Frame Shift Ins (INS) | VAF 66/364 reads (18%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.682T>G p.S228A (on ENST00000379869 / NM_001079858.3; = p.S225A on NM_005756.4) | Missense Mutation (SNP) | VAF 112/774 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ADGRL3 | c.4070G>T p.R1357L (on ENST00000506720 / NM_001322402.2; = p.R1246L on NM_015236.6) | Missense Mutation (SNP) | VAF 300/1060 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ADPRH | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 827/1267 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPS | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 450/1246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.6776A>G p.K2259R | Missense Mutation (SNP) | VAF 163/798 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AMBRA1 | c.2329G>C p.E777Q (on ENST00000458649 / NM_001367468.1; = p.E687Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/1210 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD13B | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ANKRD27 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 79/588 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ARFGAP1 | c.1057del p.D353Tfs*101 | Frame Shift Del (DEL) | VAF 136/519 reads (26%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.3088G>T p.A1030S | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ARL15 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 118/513 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASAP3 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 104/604 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATF3 | c.349-1G>C p.X117_splice | Splice Site (SNP) | VAF 36/1408 reads (3%) | called by muse, mutect2
- ATP10B | c.2422G>C p.D808H | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATXN2 | c.620C>A p.S207* (on ENST00000550104; = p.S47* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 52/334 reads (16%) | called by muse, varscan2
- AURKB | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 96/508 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- BBX | c.2601G>C p.E867D (on ENST00000325805 / NM_001142568.3; = p.E837D on NM_020235.7) | Missense Mutation (SNP) | VAF 50/964 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- C6orf58 | c.301+1G>T p.X101_splice | Splice Site (SNP) | VAF 167/609 reads (27%) | called by muse, mutect2, varscan2
- CACNB2 | c.1583C>T p.S528F (on ENST00000324631 / NM_201596.3; = p.S473F on NM_000724.4) | Missense Mutation (SNP) | VAF 99/425 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CASP8AP2 | c.230A>T p.Q77L | Missense Mutation (SNP) | VAF 191/611 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- CBY2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC166 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- CCL28 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 246/662 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CD1E | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 527/1088 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CFAP47 | c.3869G>A p.C1290Y | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CFAP97 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CLHC1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 113/1520 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.005); called by muse, mutect2
- CNTLN | c.2491A>T p.K831* | Nonsense Mutation (SNP) | VAF 85/479 reads (18%) | called by muse, mutect2, varscan2
- COL20A1 | c.3383T>A p.V1128D | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A6 | c.3302T>A p.L1101Q | Missense Mutation (SNP) | VAF 38/636 reads (6%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.977); called by muse, mutect2
- COL5A2 | c.809del p.G270Afs*29 | Frame Shift Del (DEL) | VAF 96/991 reads (10%) | called by mutect2, pindel
- COL6A6 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 96/1272 reads (8%) | called by muse, mutect2
- CPLX4 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 80/636 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- CR1 | c.5682G>T p.Q1894H | Missense Mutation (SNP) | VAF 49/457 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CR1 | c.5837del p.G1946Afs*29 | Frame Shift Del (DEL) | VAF 307/755 reads (41%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.1438A>T p.I480F | Missense Mutation (SNP) | VAF 56/541 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CRPPA | c.1272G>C p.E424D (on ENST00000407010 / NM_001368197.1; = p.E374D on NM_001101417.4) | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRX | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTNNA2 | c.2040G>C p.K680N | Missense Mutation (SNP) | VAF 61/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAP3 | c.169-2A>C p.X57_splice | Splice Site (SNP) | VAF 69/719 reads (10%) | called by muse, mutect2
- DDB1 | c.3221G>A p.R1074K | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DLG3 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 108/1172 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); called by muse, mutect2
- DMD | c.5176G>T p.D1726Y | Missense Mutation (SNP) | VAF 224/1199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- DPP10 | c.1953T>C p.G651= | Splice Region (SNP) | VAF 70/306 reads (23%) | called by muse, varscan2
- DST | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 136/519 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSTYK | c.1523T>A p.V508D | Missense Mutation (SNP) | VAF 447/856 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DTHD1 | c.486G>C p.K162N (on ENST00000456874; = p.K287N on NM_001170700.3) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DZIP3 | c.3150-1G>C p.X1050_splice | Splice Site (SNP) | VAF 132/1522 reads (9%) | called by muse, mutect2
- EDIL3 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPB41L4B | c.2302-2A>G p.X768_splice | Splice Site (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- ERICH3 | c.1542T>G p.N514K | Missense Mutation (SNP) | VAF 16/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- EYS | c.6394dup p.L2132Pfs*9 | Frame Shift Ins (INS) | VAF 42/375 reads (11%) | called by mutect2, pindel, varscan2
- FAM117A | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 207/502 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FAM120C | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 191/629 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FAM135B | c.4193T>A p.L1398* | Nonsense Mutation (SNP) | VAF 84/641 reads (13%) | called by muse, mutect2, varscan2
- FAM9B | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- FBLN5 | c.1237C>G p.P413A | Missense Mutation (SNP) | VAF 174/806 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FBXO16 | c.669T>A p.D223E | Missense Mutation (SNP) | VAF 321/1194 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FCRL2 | c.1470G>T p.R490S | Missense Mutation (SNP) | VAF 251/691 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FGD1 | c.2675T>A p.I892N | Missense Mutation (SNP) | VAF 109/1009 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FLNA | c.5269C>G p.L1757V (on ENST00000369850 / NM_001110556.2; = p.L1749V on NM_001456.3) | Missense Mutation (SNP) | VAF 162/428 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLNA | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 123/446 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FLNA | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FNDC3B | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 46/1148 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.105); called by muse, mutect2
- FSIP2 | c.4145A>T p.K1382M | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FZD6 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- GABARAPL1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 102/1128 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.312); called by muse, mutect2
- GABRA2 | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, varscan2
- GALE | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 72/370 reads (19%) | called by muse, varscan2
- GASK1B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF3 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 589/946 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GJA9 | c.547T>G p.L183V | Missense Mutation (SNP) | VAF 151/508 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GLRA2 | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 75/726 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLRB | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 151/1053 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GNAS | c.971-6A>T | Splice Region (SNP) | VAF 173/1396 reads (12%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 97/874 reads (11%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- GPR158 | c.2378dup p.E794Rfs*29 | Frame Shift Ins (INS) | VAF 128/397 reads (32%) | called by mutect2, pindel, varscan2
- GPR174 | c.682G>C p.A228P | Missense Mutation (SNP) | VAF 147/735 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRASP1 | c.2477C>A p.A826D | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GTF3A | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GUCY2D | c.2622G>C p.E874D | Missense Mutation (SNP) | VAF 29/1059 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HACE1 | c.752A>T p.Y251F | Missense Mutation (SNP) | VAF 154/999 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HCN1 | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 139/844 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- HSPG2 | c.2971T>C p.W991R | Missense Mutation (SNP) | VAF 237/853 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2C | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 258/679 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI35 | c.70T>G p.W24G | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFI44L | c.1050T>A p.G350= | Splice Region (SNP) | VAF 100/372 reads (27%) | called by muse, varscan2
- IGHV1OR15-9 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 112/786 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IRX3 | c.1271del p.P424Rfs*99 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel*, varscan2
- ITPK1 | c.120G>C p.Q40H | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR3 | c.3772-2A>T p.X1258_splice | Splice Site (SNP) | VAF 53/317 reads (17%) | called by muse, mutect2, varscan2
- JAK1 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 176/969 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- KCNC2 | c.846G>C p.L282F | Missense Mutation (SNP) | VAF 352/719 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- KDM4A | c.1657A>G p.R553G | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6A | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 38/671 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2
- KIAA0408 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF4B | c.1886C>G p.T629R | Missense Mutation (SNP) | VAF 207/1042 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KNG1 | c.1600C>G p.P534A | Missense Mutation (SNP) | VAF 677/941 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT20 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 181/545 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LIMA1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LINC01036 | n.394G>T | Splice Region (SNP) | VAF 389/882 reads (44%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.4058C>T p.S1353F | Missense Mutation (SNP) | VAF 216/2957 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRRCC1 | c.2494-2A>G p.X832_splice | Splice Site (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2, varscan2
- MAGEB6B | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 79/769 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKAPK2 | c.593G>T p.R198M | Missense Mutation (SNP) | VAF 642/1204 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MAST3 | c.3482T>C p.L1161P | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 98/312 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MYO18B | c.6761T>G p.V2254G | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NCAPG | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 85/454 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCL | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 324/815 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NDST4 | c.978G>A p.K326= | Splice Region (SNP) | VAF 20/147 reads (14%) | called by muse, varscan2
- NFATC1 | c.1699C>G p.H567D | Missense Mutation (SNP) | VAF 35/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NKRF | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 149/476 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- NOTCH1 | c.5329G>T p.E1777* | Nonsense Mutation (SNP) | VAF 156/361 reads (43%) | called by muse, mutect2, varscan2
- NR4A3 | c.1142C>A p.P381Q | Missense Mutation (SNP) | VAF 143/333 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NUS1 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 104/847 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NXF3 | c.739A>G p.M247V | Missense Mutation (SNP) | VAF 250/749 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OLFM3 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 55/424 reads (13%) | called by muse, mutect2, varscan2
- OR10Q1 | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 96/606 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- OR5H15 | c.79dup p.L27Pfs*58 | Frame Shift Ins (INS) | VAF 106/550 reads (19%) | called by pindel, varscan2
- OR8K5 | c.360T>A p.Y120* | Nonsense Mutation (SNP) | VAF 81/422 reads (19%) | called by muse, mutect2, varscan2
- OSBP | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 137/706 reads (19%) | called by muse, mutect2, varscan2
- OTOL1 | c.1033T>G p.F345V | Missense Mutation (SNP) | VAF 176/1838 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PABPC5 | c.175del p.L59Wfs*18 | Frame Shift Del (DEL) | VAF 140/753 reads (19%) | called by mutect2, varscan2
- PAOX | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 111/471 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDH11X | c.3879T>A p.D1293E | Missense Mutation (SNP) | VAF 627/2605 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH7 | c.3206G>C p.G1069A | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PKHD1 | c.6510G>C p.L2170F | Missense Mutation (SNP) | VAF 287/1071 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PLS3 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 93/752 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNLIPRP1 | c.197A>T p.N66I | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- POGK | c.89del p.P30Rfs*35 | Frame Shift Del (DEL) | VAF 304/721 reads (42%) | called by mutect2, pindel, varscan2
- POLR3C | c.1535G>C p.S512T | Missense Mutation (SNP) | VAF 57/533 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, mutect2
- POMT2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEB3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 65/1498 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, mutect2
- PPFIA2 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 163/1021 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PRR18 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PTPRF | c.2231A>G p.Y744C | Missense Mutation (SNP) | VAF 60/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RAB40B | c.139G>C p.A47P | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIPPLY1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 178/617 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROGDI | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RTL3 | c.1154T>A p.L385H | Missense Mutation (SNP) | VAF 30/1047 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- RYR1 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 90/628 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD9L | c.4592G>T p.G1531V | Missense Mutation (SNP) | VAF 182/355 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- SCML2 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 27/642 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- SENP6 | c.2874A>G p.I958M | Missense Mutation (SNP) | VAF 169/654 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SEZ6L | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHPRH | c.2113del p.H705Tfs*15 | Frame Shift Del (DEL) | VAF 122/544 reads (22%) | called by mutect2, pindel, varscan2
- SI | c.1666T>A p.Y556N | Missense Mutation (SNP) | VAF 110/1556 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC10A3 | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 60/668 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2
- SLC16A2 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 356/1159 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC22A13 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SLC22A16 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 107/683 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A5 | c.2711A>G p.D904G | Missense Mutation (SNP) | VAF 182/683 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLIT2 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 78/534 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK2 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 128/481 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMC1A | c.2894G>T p.G965V | Missense Mutation (SNP) | VAF 121/1003 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPEF2 | c.2866C>G p.L956V | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPEN | c.6892dup p.T2298Nfs*8 | Frame Shift Ins (INS) | VAF 72/550 reads (13%) | called by mutect2, pindel, varscan2
- SUCNR1 | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 83/947 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SV2C | c.381G>C p.R127S | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SYCE1 | c.631C>A p.H211N (on ENST00000343131 / NM_001143764.3; = p.H175N on NM_130784.3) | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- TAF8 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 94/389 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TAS2R39 | c.750C>G p.N250K | Missense Mutation (SNP) | VAF 73/481 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D3F | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 162/676 reads (24%) | called by mutect2, varscan2
- TCERG1 | c.1900A>G p.K634E | Missense Mutation (SNP) | VAF 102/430 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- TERT | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TFAP2A | c.1258C>T p.P420S (on ENST00000482890; = p.P412S on NM_001032280.3) | Missense Mutation (SNP) | VAF 116/951 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFAP2D | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TFPI2 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 340/688 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC2 | c.3964C>G p.P1322A | Missense Mutation (SNP) | VAF 360/1179 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- THOC2 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TICRR | c.722C>G p.T241S | Missense Mutation (SNP) | VAF 115/725 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- TLR7 | c.2986C>A p.Q996K | Missense Mutation (SNP) | VAF 199/523 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TMEM106A | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 183/605 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM132C | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TPP1 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 248/1432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TPTE | c.1499C>A p.T500K (on ENST00000618007 / NM_199261.4; = p.T482K on NM_199259.4) | Missense Mutation (SNP) | VAF 42/856 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TRDN | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRIM39 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 78/731 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM40 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 233/1044 reads (22%) | called by muse, mutect2, varscan2
- TTC14 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 321/430 reads (75%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3E | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBAP2L | c.1283C>A p.S428* | Nonsense Mutation (SNP) | VAF 155/748 reads (21%) | called by muse, mutect2, varscan2
- UGGT1 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 134/363 reads (37%) | called by muse, mutect2, varscan2
- UNC5D | c.2158T>C p.F720L | Missense Mutation (SNP) | VAF 155/575 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VIT | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 243/1320 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, varscan2
- WAC | c.947C>G p.S316* | Nonsense Mutation (SNP) | VAF 131/620 reads (21%) | called by muse, mutect2, varscan2
- WDR3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WFDC12 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 26/569 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- XIAP | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZIC3 | c.677T>A p.M226K | Missense Mutation (SNP) | VAF 138/669 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by mutect2, varscan2
- ZIC3 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 141/672 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by mutect2, varscan2
- ZNF24 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- ZNF280C | c.2157G>C p.E719D | Missense Mutation (SNP) | VAF 144/417 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ZNF454 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 116/620 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF813 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 227/1064 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ZNF853 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 126/777 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN23 | c.319T>G p.W107G | Missense Mutation (SNP) | VAF 117/470 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by mutect2, varscan2
- ZXDB | c.946A>C p.T316P | Missense Mutation (SNP) | VAF 68/774 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ADAMTS5 | c.600C>T p.F200= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1475884402, COSV53185564; called by muse, mutect2, varscan2
- AFDN | c.4764G>T p.V1588= | Silent (SNP) | VAF 217/845 reads (26%) | called by muse, mutect2, varscan2
- ANAPC4 | c.1413C>T p.N471= | Silent (SNP) | VAF 133/400 reads (33%) | catalogued as rs760577488; called by muse, mutect2, varscan2
- ANK2 | c.7947C>G p.V2649= | Silent (SNP) | VAF 190/1163 reads (16%) | called by muse, mutect2, varscan2
- APC2 | c.585C>T p.R195= | Silent (SNP) | VAF 100/514 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.4956A>G p.P1652= (on ENST00000310343 / NM_001378025.1; = p.P1303= on NM_014715.4) | Silent (SNP) | VAF 129/608 reads (21%) | catalogued as rs1380691556; called by muse, mutect2, varscan2
- ARHGEF6 | c.537G>T p.L179= | Silent (SNP) | VAF 227/1320 reads (17%) | called by muse, mutect2, varscan2
- ASB17 | c.135A>T p.P45= | Silent (SNP) | VAF 108/606 reads (18%) | called by muse, mutect2, varscan2
- ATP2B1 | c.3480C>T p.P1160= | Silent (SNP) | VAF 481/940 reads (51%) | called by muse, mutect2, varscan2
- C6orf132 | c.2586C>T p.S862= | Silent (SNP) | VAF 14/364 reads (4%) | called by muse, mutect2
- CBLN2 | c.537C>A p.V179= | Silent (SNP) | VAF 430/804 reads (53%) | called by muse, mutect2, varscan2
- CCNB3 | c.1995T>A p.A665= | Silent (SNP) | VAF 72/762 reads (9%) | called by muse, mutect2
- CCNB3 | c.3043C>T p.L1015= | Silent (SNP) | VAF 70/1059 reads (7%) | called by muse, mutect2
- CCT4 | c.1314A>G p.E438= | Silent (SNP) | VAF 448/1932 reads (23%) | called by muse, mutect2, varscan2
- CDH4 | c.2328C>G p.V776= | Silent (SNP) | VAF 93/355 reads (26%) | called by muse, mutect2, varscan2
- CDKL5 | c.1902G>T p.G634= | Silent (SNP) | VAF 453/1420 reads (32%) | called by muse, mutect2, varscan2
- CFAP46 | c.3774C>T p.V1258= | Silent (SNP) | VAF 98/214 reads (46%) | catalogued as rs1188060699; called by muse, mutect2, varscan2
- CLCN5 | c.54T>C p.F18= | Silent (SNP) | VAF 136/439 reads (31%) | called by muse, mutect2, varscan2
- CMTM4 | c.663A>T p.S221= | Silent (SNP) | VAF 102/762 reads (13%) | called by muse, mutect2, varscan2
- CNTN6 | c.2151C>A p.L717= | Silent (SNP) | VAF 48/393 reads (12%) | called by muse, mutect2, varscan2
- CSMD1 | c.6978G>T p.R2326= (on ENST00000520002; = p.R2325= on NM_033225.6) | Silent (SNP) | VAF 30/221 reads (14%) | catalogued as rs575609843; called by muse, mutect2, varscan2
- CUX2 | c.432C>T p.P144= | Silent (SNP) | VAF 87/137 reads (64%) | called by muse, mutect2, varscan2
- DENND2A | c.2484C>T p.L828= | Silent (SNP) | VAF 38/203 reads (19%) | called by muse, varscan2
- DNAH9 | c.7506G>A p.V2502= | Silent (SNP) | VAF 107/649 reads (16%) | called by muse, mutect2, varscan2
- DYSF | c.753G>A p.R251= | Silent (SNP) | VAF 228/709 reads (32%) | called by muse, mutect2, varscan2
- ENPP1 | c.2184T>C p.F728= | Silent (SNP) | VAF 355/1201 reads (30%) | called by muse, mutect2, varscan2
- FGFR3 | c.810C>T p.D270= | Silent (SNP) | VAF 34/215 reads (16%) | catalogued as rs142910057; called by muse, mutect2, varscan2
- FNDC1 | c.4929C>T p.I1643= | Silent (SNP) | VAF 158/1141 reads (14%) | catalogued as rs1209844362, COSV51948703; called by muse, mutect2, varscan2
- FREM3 | c.5529G>C p.V1843= | Silent (SNP) | VAF 174/982 reads (18%) | called by muse, mutect2, varscan2
- FREM3 | c.2409T>A p.T803= | Silent (SNP) | VAF 107/698 reads (15%) | called by muse, mutect2, varscan2
- GDF3 | c.606G>A p.L202= | Silent (SNP) | VAF 1372/2156 reads (64%) | catalogued as rs374679722; called by muse, mutect2, varscan2
- GDF6 | c.1101C>A p.G367= | Silent (SNP) | VAF 45/1741 reads (3%) | called by muse, mutect2
- GLE1 | c.906T>C p.Y302= | Silent (SNP) | VAF 40/1001 reads (4%) | called by muse, mutect2
- GLYAT | c.645C>T p.T215= | Silent (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- H6PD | c.1572G>A p.Q524= | Silent (SNP) | VAF 346/1021 reads (34%) | catalogued as rs766339404; called by muse, mutect2, varscan2
- HDAC6 | c.1023G>T p.V341= | Silent (SNP) | VAF 218/728 reads (30%) | called by muse, mutect2, varscan2
- HGH1 | c.267C>T p.A89= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- HMCN1 | c.16761G>A p.L5587= | Silent (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- KDM6A | c.3531G>C p.L1177= | Silent (SNP) | VAF 185/1476 reads (13%) | called by muse, mutect2, varscan2
- LAMA2 | c.6228C>T p.V2076= | Silent (SNP) | VAF 204/1229 reads (17%) | catalogued as rs138994246; called by muse, mutect2, varscan2
- LINGO2 | c.1179C>T p.F393= | Silent (SNP) | VAF 224/559 reads (40%) | called by muse, mutect2, varscan2
- LMNB2 | c.1362G>A p.T454= | Silent (SNP) | VAF 112/686 reads (16%) | catalogued as rs775926931; called by muse, mutect2, varscan2
- LRIG3 | c.1461C>T p.S487= | Silent (SNP) | VAF 229/400 reads (57%) | catalogued as rs1450923803; called by muse, mutect2, varscan2
- LRP1B | c.7932A>C p.I2644= | Silent (SNP) | VAF 60/814 reads (7%) | called by muse, mutect2
- MACROD1 | c.306G>A p.L102= | Silent (SNP) | VAF 109/524 reads (21%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1098C>A p.A366= | Silent (SNP) | VAF 205/986 reads (21%) | called by muse, mutect2, varscan2
- MED23 | c.1323C>T p.S441= | Silent (SNP) | VAF 336/1271 reads (26%) | called by muse, mutect2, varscan2
- MTO1 | c.210C>T p.D70= | Silent (SNP) | VAF 51/324 reads (16%) | catalogued as rs138494495; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAV3 | c.6954T>C p.D2318= (on ENST00000397909 / NM_001024383.2; = p.D2296= on NM_014903.6) | Silent (SNP) | VAF 402/789 reads (51%) | called by muse, mutect2, varscan2
- NLGN3 | c.1795C>A p.R599= (on ENST00000358741 / NM_181303.2; = p.R579= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/890 reads (12%) | catalogued as COSV100704816; called by muse, mutect2, varscan2
- NLRP5 | c.672A>G p.E224= | Silent (SNP) | VAF 81/807 reads (10%) | catalogued as COSV101173581; called by muse, mutect2, varscan2
- NMBR | c.372C>G p.L124= | Silent (SNP) | VAF 66/463 reads (14%) | called by muse, mutect2, varscan2
- NOX3 | c.66A>T p.I22= | Silent (SNP) | VAF 142/468 reads (30%) | called by muse, mutect2, varscan2
- NRXN1 | c.2151G>T p.T717= | Silent (SNP) | VAF 146/630 reads (23%) | catalogued as rs200768648; ClinVar: likely benign; called by muse, mutect2, varscan2
- OCA2 | c.1689G>T p.P563= | Silent (SNP) | VAF 302/903 reads (33%) | catalogued as COSV100667862; called by muse, mutect2, varscan2
- OR10W1 | c.708C>A p.L236= | Silent (SNP) | VAF 50/225 reads (22%) | catalogued as COSV101223650, COSV67720862; called by muse, mutect2, varscan2
- OR2M7 | c.204C>G p.L68= | Silent (SNP) | VAF 96/457 reads (21%) | catalogued as COSV58739800; called by muse, mutect2, varscan2
- PLK5 | c.894C>T p.L298= | Silent (SNP) | VAF 66/196 reads (34%) | called by muse, mutect2, varscan2
- POFUT1 | c.510C>T p.F170= | Silent (SNP) | VAF 185/722 reads (26%) | called by muse, mutect2, varscan2
- POU3F4 | c.423G>A p.V141= | Silent (SNP) | VAF 56/421 reads (13%) | called by muse, mutect2, varscan2
- PSG11 | c.165C>A p.V55= | Silent (SNP) | VAF 150/1055 reads (14%) | called by muse, mutect2, varscan2
- PTCHD1 | c.2442T>G p.A814= | Silent (SNP) | VAF 79/732 reads (11%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1173C>G p.A391= | Silent (SNP) | VAF 53/205 reads (26%) | called by muse, mutect2, varscan2
- RBBP8 | c.1068A>G p.K356= | Silent (SNP) | VAF 198/511 reads (39%) | called by muse, mutect2, varscan2
- RBM15B | c.2376G>A p.A792= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as rs1217378666; called by muse, mutect2, varscan2
- RNF39 | c.339C>T p.A113= | Silent (SNP) | VAF 16/332 reads (5%) | catalogued as rs1374822687; called by muse, mutect2
- RSPH4A | c.1674T>C p.N558= | Silent (SNP) | VAF 250/942 reads (27%) | catalogued as rs369042963; called by muse, mutect2
- SBSN | c.1263G>A p.Q421= | Silent (SNP) | VAF 56/415 reads (13%) | called by muse, mutect2, varscan2
- SCN3A | c.1839G>T p.V613= | Silent (SNP) | VAF 128/1046 reads (12%) | called by muse, mutect2, varscan2
- SLC22A15 | c.1470A>G p.L490= | Silent (SNP) | VAF 80/544 reads (15%) | catalogued as rs922651951; called by muse, mutect2, varscan2
- SMAP1 | c.1311C>T p.T437= (on ENST00000370455 / NM_001044305.3; = p.T410= on NM_021940.5) | Silent (SNP) | VAF 119/403 reads (30%) | called by muse, mutect2, varscan2
- SPEN | c.1953A>T p.P651= | Silent (SNP) | VAF 100/561 reads (18%) | catalogued as rs1557757985; called by muse, mutect2, varscan2
- SPTAN1 | c.1149C>A p.L383= | Silent (SNP) | VAF 228/1000 reads (23%) | called by muse, mutect2, varscan2
- SPTB | c.1176C>T p.I392= | Silent (SNP) | VAF 174/886 reads (20%) | called by muse, mutect2, varscan2
- TAS2R39 | c.267C>G p.L89= | Silent (SNP) | VAF 109/728 reads (15%) | called by muse, mutect2, varscan2
- TBC1D8B | c.54G>A p.L18= | Silent (SNP) | VAF 46/465 reads (10%) | called by muse, mutect2, varscan2
- TGM6 | c.1131C>A p.I377= | Silent (SNP) | VAF 296/935 reads (32%) | called by muse, mutect2, varscan2
- TMEM131 | c.4947G>C p.S1649= | Silent (SNP) | VAF 65/508 reads (13%) | catalogued as COSV51774055; called by muse, mutect2, varscan2
- TNXB | c.8949G>A p.E2983= (on ENST00000647633; = p.E2736= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/471 reads (21%) | called by muse, mutect2, varscan2
- TRAM1 | c.561A>G p.K187= | Silent (SNP) | VAF 88/515 reads (17%) | called by muse, mutect2, varscan2
- TRIM58 | c.855C>T p.L285= | Silent (SNP) | VAF 72/469 reads (15%) | called by muse, mutect2, varscan2
- TRPV6 | c.951C>G p.L317= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs1362165822, COSV63892344; called by muse, mutect2, varscan2
- TTC6 | c.2766G>A p.R922= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs970262382; called by muse, mutect2, varscan2
- TTN | c.96321C>T p.T32107= (on ENST00000591111; = p.T24683= on NM_003319.4) | Silent (SNP) | VAF 170/1255 reads (14%) | catalogued as rs765149703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.282C>T p.T94= | Silent (SNP) | VAF 69/517 reads (13%) | catalogued as rs768331775; called by muse, mutect2, varscan2
- UROC1 | c.1473C>T p.N491= | Silent (SNP) | VAF 108/1254 reads (9%) | catalogued as rs773884176; called by muse, mutect2
- USP33 | c.819A>G p.Q273= | Silent (SNP) | VAF 91/295 reads (31%) | catalogued as rs1302308638; called by muse, mutect2, varscan2
- USP34 | c.7458G>A p.V2486= | Silent (SNP) | VAF 175/1832 reads (10%) | called by muse, mutect2
- VSIG4 | c.306C>A p.T102= | Silent (SNP) | VAF 157/523 reads (30%) | called by muse, mutect2, varscan2
- WDR81 | c.4197G>C p.V1399= (on ENST00000409644 / NM_001163809.2; = p.V348= on NM_152348.4) | Silent (SNP) | VAF 68/407 reads (17%) | catalogued as COSV58488612; called by muse, mutect2, varscan2
- ZBTB20 | c.180T>G p.A60= | Silent (SNP) | VAF 212/345 reads (61%) | catalogued as rs1340765188; called by muse, mutect2, varscan2
- ZFHX4 | c.9276C>A p.I3092= | Silent (SNP) | VAF 69/544 reads (13%) | called by muse, mutect2, varscan2
- ZIM3 | c.636A>G p.K212= | Silent (SNP) | VAF 50/453 reads (11%) | called by muse, mutect2, varscan2
- ZNF182 | c.924T>C p.H308= | Silent (SNP) | VAF 36/366 reads (10%) | called by muse, mutect2
- ZNF208 | c.2457C>A p.T819= | Silent (SNP) | VAF 100/585 reads (17%) | called by muse, mutect2, varscan2
- ZNF257 | c.1197C>G p.A399= | Silent (SNP) | VAF 90/449 reads (20%) | catalogued as COSV71310577; called by muse, mutect2, varscan2
- ZNF526 | c.615C>G p.L205= | Silent (SNP) | VAF 349/1144 reads (31%) | catalogued as COSV56629804; called by muse, mutect2, varscan2
- ZSCAN16 | c.690G>A p.Q230= | Silent (SNP) | VAF 102/832 reads (12%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-652T>C | Intron (SNP) | VAF 53/311 reads (17%) | called by muse, mutect2, varscan2
- ACSF3 | c.*102A>C | 3'UTR (SNP) | VAF 207/1071 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.-22G>A | 5'UTR (SNP) | VAF 76/575 reads (13%) | catalogued as rs760846321; ClinVar: uncertain significance; called by mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 16/138 reads (12%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AL353804.6 | n.83G>C | RNA (SNP) | VAF 103/946 reads (11%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498811 T>G | 5'Flank (SNP) | VAF 132/733 reads (18%) | called by muse, mutect2, varscan2
- BLMH | c.801+12G>T | Intron (SNP) | VAF 226/704 reads (32%) | called by muse, mutect2, varscan2
- BOLA3 | c.-31G>A | 5'UTR (SNP) | VAF 127/527 reads (24%) | called by muse, mutect2, varscan2
- C22orf34 | n.862A>T | RNA (SNP) | VAF 169/529 reads (32%) | called by muse, mutect2, varscan2
- CDH8 | c.*684C>G | 3'UTR (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- CEP41 | c.*2240G>C | 3'UTR (SNP) | VAF 134/835 reads (16%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2493C>T | 3'UTR (SNP) | VAF 129/724 reads (18%) | called by muse, mutect2, varscan2
- CNKSR2 | c.520-27C>A | Intron (SNP) | VAF 59/345 reads (17%) | called by muse, mutect2, varscan2
- CNOT3 | c.2038-171A>G | Intron (SNP) | VAF 211/758 reads (28%) | called by muse, mutect2, varscan2
- CST7 | c.-29T>G | 5'UTR (SNP) | VAF 42/312 reads (13%) | called by muse, mutect2, varscan2
- DIPK1A | c.-15C>T | 5'UTR (SNP) | VAF 53/311 reads (17%) | catalogued as rs757804829; called by muse, mutect2, varscan2
- EFL1P1 | n.1511T>G | RNA (SNP) | VAF 56/376 reads (15%) | called by mutect2, varscan2
- EPDR1 | c.-23C>T | 5'UTR (SNP) | VAF 25/157 reads (16%) | catalogued as COSV52260837; called by muse, mutect2, varscan2
- EXD1 | c.691-40C>T | Intron (SNP) | VAF 60/530 reads (11%) | called by muse, varscan2
- EXOC4 | c.1418-53508G>A | Intron (SNP) | VAF 273/513 reads (53%) | called by muse, mutect2, varscan2
- GABRA3 | c.551+4608G>C | Intron (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- HCG27 | n.400A>T | RNA (SNP) | VAF 47/308 reads (15%) | called by muse, mutect2, varscan2
- HSPA9 | c.1183-28C>G | Intron (SNP) | VAF 87/413 reads (21%) | catalogued as COSV99785758; called by muse, mutect2, varscan2
- IGSF1 | c.97+21C>T | Intron (SNP) | VAF 83/544 reads (15%) | catalogued as rs1034750816, COSV63835970; called by muse, mutect2, varscan2
- ITPK1 | c.-10G>T | 5'UTR (SNP) | VAF 42/247 reads (17%) | called by muse, mutect2, varscan2
- KDM4B | c.1115+697G>A | Intron (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- KDM4B | c.1115+698A>T | Intron (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2, varscan2
- KRT17P4 | chr17:16843718 C>T | 3'Flank (SNP) | VAF 210/2266 reads (9%) | called by muse, mutect2
- LRBA | c.6363+8278C>T | Intron (SNP) | VAF 29/148 reads (20%) | catalogued as rs1206905643; called by muse, mutect2, varscan2
- NARF | c.769+1050C>T | Intron (SNP) | VAF 26/180 reads (14%) | catalogued as rs1265175781, COSV100559649; called by muse, mutect2, varscan2
- NDUFV1 | c.72+210C>T | Intron (SNP) | VAF 79/741 reads (11%) | called by muse, mutect2, varscan2
- NHSL2 | chrX:72142259 del A | 3'Flank (DEL) | VAF 91/445 reads (20%) | called by mutect2, pindel, varscan2
- NXT2 | chrX:109535894 C>A | 5'Flank (SNP) | VAF 53/516 reads (10%) | called by muse, mutect2, varscan2
- PIGQ | c.*69G>T | 3'UTR (SNP) | VAF 89/265 reads (34%) | called by muse, mutect2, varscan2
- POLB | c.913+139G>T | Intron (SNP) | VAF 161/1027 reads (16%) | called by muse, mutect2, varscan2
- PRC1 | c.1791+10G>A | Intron (SNP) | VAF 78/561 reads (14%) | called by muse, mutect2, varscan2
- PRDM15 | c.-204G>A | 5'UTR (SNP) | VAF 117/441 reads (27%) | catalogued as rs754385951, COSV54156501; called by muse, mutect2, varscan2
- PRKD1 | c.-20A>T | 5'UTR (SNP) | VAF 25/115 reads (22%) | catalogued as rs187563867; called by muse, mutect2, varscan2
- PRKN | c.-4G>A | 5'UTR (SNP) | VAF 38/361 reads (11%) | catalogued as rs746696823; called by muse, mutect2, varscan2
- PSTPIP1 | c.355-27C>T | Intron (SNP) | VAF 79/454 reads (17%) | catalogued as rs1383646414, COSV51198057; called by muse, mutect2, varscan2
- PUDP | c.62-11184G>T | Intron (SNP) | VAF 239/775 reads (31%) | catalogued as rs774543511; called by muse, mutect2, varscan2
- RCBTB2 | c.-240C>T | 5'UTR (SNP) | VAF 49/225 reads (22%) | called by muse, mutect2, varscan2
- RFPL4AL1 | chr19:55778388 C>A | 3'Flank (SNP) | VAF 184/728 reads (25%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.75G>A | RNA (SNP) | VAF 87/1184 reads (7%) | called by muse, mutect2
- RPS4X | c.361-38A>G | Intron (SNP) | VAF 143/583 reads (25%) | called by muse, mutect2, varscan2
- RYR2 | c.11146-1208T>A | Intron (SNP) | VAF 90/710 reads (13%) | called by muse, varscan2
- SCNN1A | chr12:6375604 G>C | 5'Flank (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1230A>T | RNA (SNP) | VAF 273/669 reads (41%) | called by muse, mutect2, varscan2
- SSR4 | c.-68G>T | 5'UTR (SNP) | VAF 56/302 reads (19%) | called by muse, mutect2, varscan2
- STAG1 | c.*6G>T | 3'UTR (SNP) | VAF 51/796 reads (6%) | called by muse, mutect2
- TARS2 | c.387+43A>G | Intron (SNP) | VAF 129/1190 reads (11%) | called by muse, mutect2, varscan2
- TMEM63B | c.711+107del | Intron (DEL) | VAF 248/961 reads (26%) | called by mutect2, pindel, varscan2
- TNFRSF25 | c.*244C>A | 3'UTR (SNP) | VAF 108/702 reads (15%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1278G>A | RNA (SNP) | VAF 137/725 reads (19%) | catalogued as rs763460461; called by muse, mutect2, varscan2
- TRDN | c.484+1200C>A | Intron (SNP) | VAF 279/1012 reads (28%) | called by muse, mutect2, varscan2
- TRIP10 | c.-39G>C | 5'UTR (SNP) | VAF 9/55 reads (16%) | catalogued as rs1235412583; called by muse, mutect2, varscan2
- TUBB8 | c.-7C>A | 5'UTR (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- UTRN | c.7479+6255G>T | Intron (SNP) | VAF 73/407 reads (18%) | called by muse, mutect2, varscan2
- VAPB | c.*4370C>T | 3'UTR (SNP) | VAF 131/905 reads (14%) | called by muse, mutect2, varscan2
- VSIG4 | chrX:66018900 A>G | 3'Flank (SNP) | VAF 64/406 reads (16%) | called by muse, mutect2, varscan2
- VSIG4 | c.962+11C>G | Intron (SNP) | VAF 182/583 reads (31%) | catalogued as COSV66074055; called by muse, mutect2, varscan2
- XAGE2 | c.*35A>T | 3'UTR (SNP) | VAF 219/599 reads (37%) | called by muse, mutect2, varscan2
- XIAP | chrX:123860226 C>T | 5'Flank (SNP) | VAF 76/693 reads (11%) | called by muse, mutect2, varscan2
- XIAP | c.*1749G>C | 3'UTR (SNP) | VAF 134/450 reads (30%) | called by muse, mutect2, varscan2
- ZNF137P | n.1705A>T | RNA (SNP) | VAF 202/815 reads (25%) | called by muse, mutect2, varscan2
- ZNF354B | c.-30C>G | 5'UTR (SNP) | VAF 9/39 reads (23%) | called by mutect2, varscan2
- ZRSR2 | c.203+1573C>G | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
